Gene-level copy-number profile of tumor specimen HTMCP-01-16-00267-01A from CGCI case HTMCP-01-16-00267, project CGCI-HTMCP-DLBCL (HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 53.7 years (19,616 days).
Specimen HTMCP-01-16-00267-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8eeb1950-a01e-49fe-84e3-5b7939f53e0e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-01-16-00267-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,732 have no estimate.
https://portal.gdc.cancer.gov/files/64b1c559-c9ae-4fad-8756-4443f6c71844

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 585; copy number 1: 7,620; copy number 2: 45,476; copy number 3: 5,138; copy number 4: 58; copy number 6: 10; copy number 7: 1; copy number 8: 3.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:137,143,820–137,996,147, 13 genes: IL22RA2, IFNGR1, OLIG3, BTF3L4P3, AL356234.2, AL356234.1, LINC02539, Y_RNA, WAKMAR2, TNFAIP3, LINC02528, LINC02865, RPSAP42.
- chr15:34,415,450–34,521,791, 4 genes (within-gene range 0–2): AC025678.3, HNRNPLP2, FSCN1P1, DNM1P5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:57,828,331–57,837,046, 2 genes, copy number 8: AC023141.7, AC023141.13.
- chr9:40,883,634–40,883,763, 1 gene, copy number 7: AL353626.2.
- chr9:64,621,560–65,193,610, 10 genes, copy number 6: AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2, BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P, BMS1P12.
- chr15:22,125,511–22,126,434, 1 gene, copy number 8 (within-gene range 3–8): OR4N3P.

Autosomal genes at a single copy (total copy number 1): 6,363. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
